Somatic mutation profile of tumor specimen TCGA-09-1674-01A (aliquot TCGA-09-1674-01A-01W-0633-09) from TCGA case TCGA-09-1674, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.1 years (28,878 days).
Specimen TCGA-09-1674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e19772a-33f4-4c06-854c-0b873444e6d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1674-10A (Blood Derived Normal), aliquot TCGA-09-1674-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b193a49-d9d0-4a8d-b841-0aa703c28731

The open-access MAF lists 127 somatic variants for this specimen: 99 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 26, Frame Shift Ins 7, Nonsense Mutation 3, Frame Shift Del 3, 3'UTR 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3188G>A p.R1063H | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs776454235, COSV50787375; called by muse, mutect2, varscan2
- ADGRF1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs773948526, COSV51945392; called by muse, mutect2, varscan2
- AGAP3 | c.2378C>A p.S793Y (on ENST00000622464; = p.S829Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV68245817, COSV68246576; called by muse, mutect2, varscan2
- ALG1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52159306; called by muse, mutect2, varscan2
- ALG10 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56794110; called by muse, mutect2, varscan2
- AP1G2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458670003, COSV58115490; called by muse, mutect2, varscan2
- BRINP2 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763946593, COSV64180023; called by muse, mutect2, varscan2
- C16orf70 | c.1230dup p.R411Qfs*4 | Frame Shift Ins (INS) | VAF 20/176 reads (11%) | catalogued as rs539297455; called by mutect2, varscan2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | catalogued as rs780657010; called by mutect2, varscan2
- CALM2 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV55400477; called by muse, mutect2, varscan2
- CCAR2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV51516564; called by muse, mutect2, varscan2
- CCDC181 | c.1211G>A p.S404N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV63158019; called by muse, mutect2, varscan2
- CELA2A | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100657461, COSV62748023; called by muse, mutect2, varscan2
- CNTN6 | c.2680G>A p.V894I | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.815); catalogued as COSV63188484; called by muse, mutect2, varscan2
- COL17A1 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 175/354 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV62229236; called by muse, mutect2, varscan2
- COL4A4 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100307657; called by muse, varscan2
- COL4A5 | c.3927T>G p.G1309= | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60371213; called by muse, mutect2, varscan2
- CSNK1D | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV53927071; called by muse, mutect2, varscan2
- CUX1 | c.1443C>A p.Y481* (on ENST00000437600 / NM_181500.4; = p.Y483* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV99476651; called by muse, mutect2
- DESI2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55643023; called by muse, mutect2, varscan2
- DGKD | c.2699G>T p.R900L (on ENST00000264057 / NM_152879.3; = p.R856L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51083506; called by muse, mutect2, varscan2
- EDC4 | c.3126C>A p.S1042R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV59303790; called by muse, mutect2, varscan2
- EGLN2 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 1963/2237 reads (88%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV58280996; called by muse, mutect2, varscan2
- EIF3B | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs371362324; called by muse, mutect2, varscan2
- ERN1 | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV70504582; called by muse, mutect2, varscan2
- F11 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 114/120 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV53004862; called by muse, mutect2, varscan2
- FAM78B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 220/526 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as rs368578294; called by muse, mutect2, varscan2
- FBXO7 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV56681304; called by muse, mutect2, varscan2
- FOXJ2 | c.1685A>T p.E562V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV50824040; called by muse, mutect2, varscan2
- GAPVD1 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV52927207; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | PolyPhen probably damaging (0.996); catalogued as COSV61321689; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 18/118 reads (15%) | catalogued as rs752075537; called by mutect2, varscan2
- H1-4 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56801235, COSV56803393; called by muse, mutect2, varscan2
- H2BC12 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV100804581, COSV100804760; called by muse, mutect2
- HEXA | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 87/90 reads (97%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs199578185, COSV51508853; called by muse, mutect2, varscan2
- IPO9 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs772200767, COSV64235851; called by muse, mutect2, varscan2
- KHDRBS2 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55489216; called by muse, mutect2, varscan2
- KIF13B | c.3593C>A p.A1198E | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV72954507, COSV72954688; called by muse, mutect2, varscan2
- KSR2 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as COSV56682710; called by muse, mutect2, varscan2
- LAMC1 | c.946T>A p.C316S | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51173930; called by muse, mutect2, varscan2
- LPP | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57113338; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 44/222 reads (20%) | catalogued as rs757410385; called by mutect2, varscan2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | catalogued as rs759630213; called by mutect2, pindel
- MAP10 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV69364816; called by muse, mutect2, varscan2
- MITD1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV56806992, COSV99175597; called by muse, mutect2, varscan2
- MST1R | c.4094C>A p.P1365H | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.105); catalogued as COSV56573572; called by muse, mutect2, varscan2
- MYLK | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV60621816; called by muse, mutect2, varscan2
- NOTCH4 | c.2438+1G>A p.X813_splice | Splice Site (SNP) | VAF 48/200 reads (24%) | catalogued as COSV66683611; called by muse, mutect2, varscan2
- NPHS2 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV62634700, COSV62636513; called by muse, varscan2
- OR1L4 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777127805, COSV52341440; called by muse, mutect2, varscan2
- OR4C13 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV73648915; called by muse, mutect2, varscan2
- OR4N2 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 74/660 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100269976; called by muse, mutect2
- PALB2 | c.1498T>C p.S500P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs869025294, COSV55162207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE1C | c.988C>G p.R330G | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58525641, COSV58527623; called by muse, mutect2, varscan2
- PDZD7 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV64647452; called by muse, mutect2, varscan2
- PHACTR3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 128/411 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763187430, COSV63030491; called by muse, mutect2, varscan2
- PHLPP2 | c.1885A>G p.N629D | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100673811; called by muse, mutect2
- PIK3CB | c.2624C>A p.A875D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56690008; called by muse, mutect2, varscan2
- PKHD1 | c.10487T>G p.L3496W | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64399500; called by muse, mutect2, varscan2
- PLEKHA4 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54365911; called by muse, mutect2, varscan2
- PLEKHG4B | c.3127G>A p.V1043I (on ENST00000283426; = p.V1399I on NM_052909.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs376759485; called by muse, mutect2
- POTEE | c.2348A>G p.E783G | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58243351; called by muse, mutect2, varscan2
- PPP1R21 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54288710; called by muse, mutect2, varscan2
- PRKAB2 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781869751, COSV54212581, COSV54214617; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.968C>T p.P323L (on ENST00000352766; = p.P244L on NM_181334.5) | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61236100; called by muse, mutect2, varscan2
- PRX | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 1373/1563 reads (88%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1349197366, COSV52533128; called by muse, mutect2, varscan2
- RFX3 | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56524399; called by muse, mutect2, varscan2
- RIF1 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54623633; called by muse, mutect2, varscan2
- RPTN | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 333/2105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60169076; called by muse, mutect2, varscan2
- RUNDC1 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV64512610; called by muse, mutect2, varscan2
- SCRN1 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as COSV54133898; called by muse, mutect2, varscan2
- SEC16B | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs376044643; called by muse, mutect2
- SETD2 | c.6589G>C p.V2197L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV57450731; called by muse, mutect2, varscan2
- SFTPA1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 170/689 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100957170; called by muse, mutect2, varscan2
- SGSM2 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 97/105 reads (92%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV52161541; called by muse, mutect2, varscan2
- SH3PXD2A | c.2548G>A p.A850T (on ENST00000369774 / NM_001365079.1; = p.A822T on NM_014631.2) | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.5); catalogued as rs764554398, COSV60120511; called by muse, mutect2, varscan2
- SORL1 | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV52761994, COSV52763102; called by muse, mutect2, varscan2
- TARDBP | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV53571252; called by muse, mutect2, varscan2
- THOC6 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV50188195; called by muse, mutect2
- TMEM130 | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 52/310 reads (17%) | catalogued as rs1343939802, COSV59560963; called by muse, mutect2, varscan2
- TMEM14A | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs1198046344, COSV52986514; called by muse, mutect2, varscan2
- TP53 | c.561_562insA p.L188Tfs*21 | Frame Shift Ins (INS) | VAF 200/274 reads (73%) | catalogued as COSV53564719; called by mutect2, pindel, varscan2
- TRIM2 | c.93G>C p.K31N (on ENST00000437508; = p.K58N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs761716930, COSV58638366; called by muse, mutect2, varscan2
- TRRAP | c.4856dup p.A1620Cfs*35 (on ENST00000359863 / NM_001244580.1; = p.A1602Cfs*35 on NM_003496.3) | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | catalogued as rs781980072; called by mutect2, varscan2
- TTN | c.65800G>A p.G21934S (on ENST00000591111; = p.G14510S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | PolyPhen possibly damaging (0.798); catalogued as COSV60323686; called by muse, mutect2, varscan2
- TTN | c.40385G>A p.R13462Q (on ENST00000591111; = p.R6038Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | PolyPhen possibly damaging (0.576); catalogued as rs771113343, COSV59942386, COSV60323737; called by muse, mutect2, varscan2
- UGT1A6 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM066253, COSV59390188, COSV59397553; called by muse, mutect2, varscan2
- WDR11 | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV54792855; called by muse, mutect2, varscan2
- ZFHX4 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51494117; called by muse, mutect2, varscan2
- ZNF213 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.135); catalogued as COSV67728274; called by muse, mutect2, varscan2
- ZNF44 | c.750T>G p.C250W (on ENST00000356109 / NM_001164276.2; = p.C202W on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61136254; called by muse, mutect2, varscan2
- ZNF551 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as COSV56594924; called by muse, mutect2, varscan2
- ZNF804A | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs749835146, COSV56469768; called by muse, mutect2, varscan2
- ZNF804B | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100306021; called by muse, mutect2
- ZNF804B | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60852751; called by muse, mutect2, varscan2
- ZNF83 | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV56532102; called by muse, mutect2, varscan2
- CFAP36 | c.711del p.S238Pfs*7 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- NCOA1 | c.4138_4139del p.E1380Sfs*15 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | called by mutect2, pindel, varscan2
- RB1 | c.1321del p.I441Lfs*16 | Frame Shift Del (DEL) | VAF 26/38 reads (68%) | called by mutect2, pindel, varscan2
- C9orf131 | c.2157C>T p.S719= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs1319702027, COSV56613990; called by muse, mutect2, varscan2
- CCDC7 | c.3615A>G p.K1205= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV56551305; called by muse, mutect2, varscan2
- CHD4 | c.846T>C p.D282= | Silent (SNP) | VAF 70/492 reads (14%) | catalogued as COSV58910221; called by muse, mutect2, varscan2
- CLEC4M | c.627G>C p.T209= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs59003279; called by muse, varscan2
- COL4A4 | c.1509C>T p.G503= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs759563620, COSV100307658, COSV100307968; called by muse, varscan2
- CPA3 | c.849G>C p.T283= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV56047209; called by muse, mutect2, varscan2
- CR1 | c.5055C>A p.L1685= | Silent (SNP) | VAF 70/212 reads (33%) | catalogued as COSV65462789; called by muse, mutect2, varscan2
- CRISP3 | c.222G>A p.V74= (on ENST00000371159 / NM_001368123.1; = p.V56= on NM_006061.4) | Silent (SNP) | VAF 52/254 reads (20%) | catalogued as COSV53818966, COSV53823097; called by muse, varscan2
- DAW1 | c.702C>A p.I234= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV59368861; called by muse, mutect2, varscan2
- FMN2 | c.1776G>A p.S592= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as rs766920101, COSV60451932; called by muse, mutect2, varscan2
- GIMAP1 | c.342G>A p.A114= | Silent (SNP) | VAF 56/101 reads (55%) | catalogued as rs754697498, COSV56188736; called by muse, mutect2, varscan2
- GPD1 | c.597C>A p.I199= | Silent (SNP) | VAF 117/231 reads (51%) | catalogued as COSV56549004; called by muse, mutect2, varscan2
- HCRTR2 | c.324T>G p.L108= | Silent (SNP) | VAF 42/228 reads (18%) | catalogued as COSV63798889; called by muse, mutect2, varscan2
- NBAS | c.5370G>A p.K1790= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV55736798; called by muse, mutect2, varscan2
- NFE2L1 | c.1875C>T p.F625= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as COSV62583769; called by muse, mutect2, varscan2
- NINL | c.2013G>A p.V671= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV54008364; called by muse, mutect2, varscan2
- PMEL | c.108A>C p.S36= | Silent (SNP) | VAF 88/544 reads (16%) | catalogued as COSV62430070; called by muse, mutect2, varscan2
- RPP38 | c.507C>T p.A169= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV100975633; called by muse, mutect2
- SEMA3E | c.984C>T p.L328= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- SLC38A11 | c.435A>T p.S145= (on ENST00000409149 / NM_001351539.1; = p.S123= on NM_173512.2) | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV58056038; called by muse, mutect2, varscan2
- STX2 | c.339G>A p.R113= | Silent (SNP) | VAF 18/225 reads (8%) | catalogued as COSV99893225; called by muse, mutect2
- TMEM177 | c.511C>T p.L171= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV55609593; called by muse, mutect2, varscan2
- TMEM182 | c.327A>C p.A109= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV68425491; called by muse, mutect2, varscan2
- TTC17 | c.3039G>A p.T1013= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as rs375047326, COSV50019362; called by muse, mutect2, varscan2
- USP42 | c.864G>C p.S288= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV60364143; called by muse, mutect2, varscan2
- ZNF319 | c.750C>T p.R250= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- NT5C1B-RDH14 | c.*38G>C | 3'UTR (SNP) | VAF 30/146 reads (21%) | catalogued as COSV67119453; called by muse, mutect2, varscan2
- ZNF597 | c.*2G>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100072152; called by muse, mutect2, varscan2
